Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAXW, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAXW-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
Thymoma, type B2, malignant
858413
Site: Thymus C37.9
Q5 5/21/14

Patient Name:

MRN:

DOB: (Age:)

Gender:r

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: THYMUS GLAND, THYMOMA, AND PERICARDIUM (long stitch on pericardium, short stitch on left lobe of gland)

DIAGNOSIS

1. Thymus gland

a) Thymoma with focal microscopic extension beyond limiting capsule into immediately adjacent mediastinal fat, 3.0 cm maximum dimension.

See comment.

b) Background non-neoplastic thymus shows involution consistent with patient's age

c) No significant lymphoid hyperplasia evident

COMMENT

The sections show a "predominantly mixed" (Lattes/Bernatz), "cortical type" (Muller Hemelink), "Type B2" (WHO) thymoma. In most areas this lobulated tumor is confined by an external capsule and is well within the external margin of the specimen as indicated by prior AgNO3 application. However, the tumor does extend directly through the capsule into the adjacent mediastinal connective tissue in several areas and in at least 2 such areas the tumor appears to be essentially juxtaposed to the external margin of the specimen. By convention therefore the tumor is considered to be a malignant thymoma and consideration should be given to the possibility of incomplete resection. There is no tumor extension to or into the patch of pericardium which was marked by a long stitch.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

MEDIASTINAL MASS

Status: complete

Page: 1 of 2

[page 2 of 2]
Patient Name:

MRN:

DOB: (Age:)

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

GROSS DESCRIPTION

The specimen container labeled with the patient's name and as "thymus gland, thymoma and pericardium (long stitch on pericardium, short stitch on left lobe of gland", contains a single piece of oriented yellow fatty soft tissue measuring 13.0 x 11.0 x 2.5 cm in thickness received in 10% buffered formalin. The specimen weighs 63.2 grams. The entire specimen is painted with silver nitrate. The specimen is oriented as short stitch on left lobe and long stitch on pericardium. A piece of grayish-tan pericardium tissue measures 2.4 x 1.5 cm. The edges of the pericardium are over coated with green dye. On sectioning, there is a tumour on the mid aspect of the left lobe measuring 3.0 x 1.3 cm maximum dimension.

Sections are submitted as follows:

1A to 1H - Representative transverse sections of the tumour in relations to the adjacent soft tissue and pericardium.

1I - Representative section from the lower left lobe.

1J - Representative section from the upper left lobe.

1K - Representative section from the upper right lobe.

1L - Representative section from the lower right lobe.

Three pieces of tumoral tissue and three pieces of thymic tissue are taken for tissue frozen.

Status: complete

Page: 2 of 2

Source: NCI Genomic Data Commons file 5722687b-9cc8-4d03-b2d3-10bf76130027 (TCGA-XU-AAXW.3D1B36F9-8DA7-4303-ABB6-31C62324FC7E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).